Gene-level copy-number profile of tumor specimen TCGA-D5-6540-01A from TCGA case TCGA-D5-6540, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 66.5 years (24,282 days).
Specimen TCGA-D5-6540-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.068eb7ab-7063-4196-9816-d23b6e331da6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6540-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/edf53f72-aec7-4fd1-ad2a-afe6e3cb42a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,382; copy number 2: 53,678; copy number 3: 3,760.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6540-01A-11D-1717-01): tumor purity 0.76, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
